Gene-level copy-number profile of tumor specimen TCGA-NI-A8LF-01A from TCGA case TCGA-NI-A8LF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 74.4 years (27,162 days).
Specimen TCGA-NI-A8LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.58fe8e32-096b-4a2b-8972-8c8868cab72b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NI-A8LF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c342cf8d-b963-454d-b534-3a0261884a30

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,159; copy number 2: 10,518; copy number 3: 21,951; copy number 4: 19,669; copy number 5: 5,698; copy number 6: 522; copy number 7: 270; copy number 8: 6; copy number 9: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NI-A8LF-01A-11D-A35Y-01): tumor purity 0.63, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:191,267,168–191,330,536, 1 gene: UTS2B.
- chr4:175,574,868–175,576,140, 1 gene: ADAM20P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 281 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:177,170,958–177,282,422, 1 gene, copy number 7: BRINP2.
- chr4:129,771,596–129,975,329, 2 genes, copy number 7 (within-gene range 4–7): LINC02465, EEF1GP8.
- chr5:55,625,845–56,491,499, 24 genes, copy number 7 (within-gene range 4–7): SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1.
- chr5:134,905,120–135,007,959, 1 gene, copy number 7 (within-gene range 4–7): PCBD2.
- chr5:134,967,907–135,034,813, 2 genes, copy number 7: CATSPER3, PITX1.
- chr5:135,034,521–135,139,681, 4 genes, copy number 7: AC008406.3, C5orf66-AS1, AC008406.2, AC008406.1.
- chr7:88,420,167–89,338,528, 11 genes, copy number 7 (within-gene range 4–7): AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr16:15,434,475–15,857,028, 12 genes, copy number 9 (within-gene range 5–9): BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3.
- chr18:47,390–9,538,114, 188 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:5,126,879–5,503,189, 6 genes, copy number 8 (within-gene range 5–8): CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3.
- chr22:19,667,023–20,208,524, 30 genes, copy number 7: AC000067.1, SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896.

Autosomal genes at a single copy (total copy number 1): 1,159. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
